Somatic mutation profile of tumor specimen TCGA-EY-A1GR-01A (aliquot TCGA-EY-A1GR-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.9 years (24,784 days).
Specimen TCGA-EY-A1GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83fb85d3-1a0c-4f8b-88bb-42c1b99a05a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GR-10A (Blood Derived Normal), aliquot TCGA-EY-A1GR-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a87416f3-c6b0-41b3-bf7b-0b669304a707

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Frame Shift Del 4, Nonsense Mutation 3, Translation Start Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/16 reads (94%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACVR1B | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57777072; called by muse, mutect2, varscan2
- CACNA2D1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as rs1207058202, COSV100667603; called by muse, mutect2, varscan2
- CCT2 | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs146372909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754864348, COSV99849706; called by muse, mutect2, varscan2
- CEP250 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs372510691, COSV100699244; called by muse, mutect2, varscan2
- CES1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as COSV100828847, COSV62087301; called by muse, mutect2, varscan2
- DNAH9 | c.4181G>A p.G1394D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs766106564, COSV99308784; called by muse, mutect2, varscan2
- DNAH9 | c.11689A>C p.T3897P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99308787; called by muse, mutect2, varscan2
- EHHADH | c.1925G>C p.S642T | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99213177, COSV99213413; called by muse, mutect2, varscan2
- FGF7 | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV51066178, COSV99983662; called by muse, mutect2, varscan2
- GDPD2 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100978728; called by muse, mutect2, varscan2
- GP6 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100117801; called by muse, mutect2, varscan2
- HAP1 | c.928C>G p.H310D | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV100170102; called by muse, mutect2, varscan2
- HECTD4 | c.5673G>C p.K1891N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV101108426; called by muse, mutect2, varscan2
- IL15RA | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs775877874, COSV101181933; called by muse, mutect2, varscan2
- ITGA11 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100242349; called by muse, mutect2, varscan2
- KCTD10 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257355894, COSV99949384, COSV99949486; called by muse, mutect2, varscan2
- KDSR | c.919del p.Y307Tfs*8 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs867247369; called by mutect2, pindel, varscan2
- KMT2C | c.14416C>T p.R4806* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV51308724, COSV51476088; called by muse, mutect2, varscan2
- LY75-CD302 | c.5382C>G p.C1794W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99374684; called by muse, varscan2
- MYRIP | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs762800014, COSV56861487; called by muse, mutect2, varscan2
- NOMO2 | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100395866; called by muse, mutect2, varscan2
- OR52K1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs764742409, COSV56904516; called by muse, mutect2, varscan2
- POF1B | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs769700681, COSV53134884; called by muse, mutect2, varscan2
- PRKACG | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1421325147, COSV99598628; called by muse, mutect2, varscan2
- PRMT9 | c.85T>G p.L29V | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100482431; called by muse, mutect2, varscan2
- PYHIN1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100932433; called by muse, mutect2, varscan2
- RPS6KA6 | c.248C>A p.S83* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99425622; called by muse, mutect2, varscan2
- RSPH14 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99321325; called by muse, mutect2, varscan2
- SRSF5 | c.408T>G p.F136L | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99384560; called by muse, mutect2, varscan2
- STYXL2 | c.2211G>C p.Q737H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54806116; called by muse, mutect2, varscan2
- TAS2R39 | c.917del p.S306Tfs*6 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as COSV101489417; called by mutect2, pindel, varscan2
- TFEB | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100026516; called by muse, mutect2, varscan2
- USP12 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99997898; called by muse, mutect2, varscan2
- ADAM2 | c.1379_1381del p.G460_S461delinsA | In Frame Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1813del p.D605Tfs*57 (on ENST00000521381 / NM_181523.3; = p.D335Tfs*57 on NM_181504.4) | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, pindel, varscan2
- UNC45A | c.1688_1689del p.E563Vfs*38 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- BNIP5 | c.1290G>A p.R430= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV101465102, COSV101465199; called by muse, mutect2, varscan2
- COL6A6 | c.2103T>A p.T701= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV62028783; called by muse, mutect2, varscan2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- GALNT3 | c.1854C>T p.C618= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV101205030; called by muse, mutect2, varscan2
- GDAP1L1 | c.54C>A p.S18= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV100697693; called by muse, mutect2, varscan2
- IL16 | c.1497G>A p.P499= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs752281273, COSV57262960; called by muse, mutect2, varscan2
- LRP2 | c.13848A>T p.S4616= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99790684; called by muse, mutect2, varscan2
- MAGEL2 | c.2952C>T p.S984= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs573975752, COSV100046329; called by muse, mutect2, varscan2
- NLRP10 | c.1014C>T p.F338= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV100150026; called by muse, mutect2, varscan2
- PRDM2 | c.4546C>A p.R1516= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV52446464, COSV99342947; called by muse, mutect2, varscan2
- TC2N | c.1413A>G p.K471= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV100563212; called by muse, mutect2
- TSR1 | c.1857A>C p.G619= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV100027261; called by muse, mutect2, varscan2
- ZNF592 | c.2493C>T p.F831= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV55439750; called by muse, mutect2, varscan2
- ZNF83 | c.699C>T p.Y233= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs566776221, COSV56529691; called by muse, mutect2, varscan2
- NOP58 | c.122+1296C>G | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99970907; called by muse, mutect2, varscan2
